Gene-level copy-number profile of tumor specimen C3L-07154-02 from CPTAC case C3L-07154, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 53.8 years (19,644 days).
Specimen C3L-07154-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 62788fe0-705d-4a82-8f95-c660bb13f7e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07154-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/2e8d43fa-b823-499e-b8e3-00dd4f8cf304

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 538; copy number 1: 21,028; copy number 2: 33,897; copy number 3: 3,186; copy number 4: 121; copy number 7: 15; copy number 8: 13; copy number 10: 22; copy number 13: 12; copy number 14: 25; copy number 18: 16; copy number 21: 8; copy number 23: 5; copy number 24: 4; copy number 26: 13; copy number 50: 3.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,020,131–52,348,671, 14 genes (within-gene range 0–1): TXNDC12, AL445685.3, KTI12, AL445685.1, TXNDC12-AS1, BTF3L4, ZFYVE9, RN7SL788P, AL139156.2, AL139156.1, PDCL3P6, AL139156.3, DNAJC19P7, ANAPC10P1.
- chr9:9,090,898–9,442,380, 2 genes (within-gene range 0–1): RPS26P3, RN7SL5P.
- chr15:57,246,960–57,278,673, 2 genes (within-gene range 0–1): HNRNPA3P11, SNORD13D.
- chr17:11,598,470–12,021,508, 5 genes (within-gene range 0–1): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1.
- chr17:12,036,496–12,036,637, 1 gene (within-gene range 0–1): RNU11-2P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 136 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:64,759,484–71,586,310, 136 genes, copy number 7–50 (within-gene range 1–50) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
